Somatic mutation profile of tumor specimen 0DQC1Z from CCDI case PBCEHF, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Glioma, malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 17.1 years (6,245 days).
Specimen 0DQC1Z: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 36f799ca-9b6e-424c-a677-76b5a04668e2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DQC24 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7f68d994-5b75-459f-8224-70708726bec5

The open-access MAF lists 52 somatic variants for this specimen: 36 protein-altering or splice-affecting, 11 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 30, Silent 11, Intron 3, Frame Shift Del 3, Nonsense Mutation 2, 5'UTR 2, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- H3-3A | c.103G>A p.G35R | Missense Mutation (SNP) | VAF 104/382 reads (27%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.773); catalogued as rs1553260624, COSV64731793, COSV64731830, COSV64732212; ClinVar: other; called by muse, mutect2, varscan2
- TP53 | c.844C>T p.R282W | Missense Mutation (SNP) | VAF 179/541 reads (33%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs28934574, CM056413, CM920678, COSV52662048, COSV52662222, COSV52701296; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AHNAK2 | c.8598del p.S2867Pfs*13 | Frame Shift Del (DEL) | VAF 19/50 reads (38%) | catalogued as rs766548544; called by mutect2, varscan2
- ATRX | c.6391C>T p.R2131* | Nonsense Mutation (SNP) | VAF 277/342 reads (81%) | catalogued as COSV64873907, COSV64881210; called by muse, mutect2, varscan2
- CHD5 | c.2929G>A p.G977R | Missense Mutation (SNP) | VAF 18/187 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.489); catalogued as rs1474737639; called by muse, mutect2
- CPAMD8 | c.3499G>A p.A1167T (on ENST00000651564; = p.A1120T on NM_015692.5) | Missense Mutation (SNP) | VAF 56/147 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); catalogued as rs372897642; called by muse, mutect2, varscan2
- EDN2 | c.496C>T p.R166W | Missense Mutation (SNP) | VAF 138/349 reads (40%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs764912588, COSV101006296; called by muse, mutect2, varscan2
- ERRFI1 | c.1118C>T p.A373V | Missense Mutation (SNP) | VAF 213/547 reads (39%) | SIFT tolerated (0.16); PolyPhen benign (0.439); catalogued as rs891908965; called by muse, mutect2, varscan2
- FLG | c.7718G>T p.S2573I | Missense Mutation (SNP) | VAF 16/142 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.245); catalogued as COSV64245954; called by muse, mutect2, varscan2
- GTF3C3 | c.389G>A p.R130H | Missense Mutation (SNP) | VAF 179/553 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs1246832442; called by muse, mutect2, varscan2
- LRRIQ3 | c.686T>C p.F229S | Missense Mutation (SNP) | VAF 113/595 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.71); catalogued as rs772702992; called by muse, mutect2, varscan2
- LYNX1-SLURP2 | c.361G>A p.A121T | Missense Mutation (SNP) | VAF 31/77 reads (40%) | SIFT tolerated (0.1); PolyPhen benign (0.132); catalogued as rs770280004, COSV58186957; called by muse, mutect2, varscan2
- MFSD9 | c.629T>C p.L210P | Missense Mutation (SNP) | VAF 134/379 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1314099941; called by muse, mutect2, varscan2
- MST1R | c.3194C>T p.A1065V | Missense Mutation (SNP) | VAF 72/243 reads (30%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as rs754028685, COSV56566260; called by muse, mutect2, varscan2
- MYH1 | c.325C>T p.R109C | Missense Mutation (SNP) | VAF 85/685 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs374097415; called by muse, mutect2, varscan2
- MYOC | c.898G>T p.E300* | Nonsense Mutation (SNP) | VAF 53/155 reads (34%) | catalogued as COSV50679209, COSV99231790; called by muse, mutect2, varscan2
- OXTR | c.998C>T p.T333M | Missense Mutation (SNP) | VAF 36/482 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.815); catalogued as rs200966415; called by muse, mutect2
- P2RY8 | c.665G>A p.R222H | Missense Mutation (SNP) | VAF 25/149 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.176); catalogued as rs765555908, COSV67177238; called by muse, mutect2, varscan2
- PCLO | c.2090C>T p.A697V | Missense Mutation (SNP) | VAF 61/264 reads (23%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as rs1398274156, COSV61616037; called by muse, mutect2, varscan2
- PDGFRA | c.937G>C p.G313R | Missense Mutation (SNP) | VAF 280/688 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as COSV57273098, COSV57275974; called by muse, mutect2, varscan2
- PKP2 | c.950C>T p.A317V | Missense Mutation (SNP) | VAF 66/160 reads (41%) | SIFT tolerated (0.94); PolyPhen benign (0); catalogued as rs775318947, COSV50725802; called by muse, mutect2, varscan2
- SLC17A6 | c.1417C>T p.R473C | Missense Mutation (SNP) | VAF 161/463 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.033); catalogued as rs747779446, COSV54141742, COSV99581096; called by muse, mutect2, varscan2
- SLC9A3 | c.463G>A p.A155T | Missense Mutation (SNP) | VAF 18/110 reads (16%) | SIFT tolerated (0.18); PolyPhen benign (0.099); catalogued as rs755902342; called by muse, mutect2, varscan2
- UTP15 | c.1226C>T p.A409V | Missense Mutation (SNP) | VAF 159/661 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs761103496, COSV57145916; called by muse, mutect2, varscan2
- VWF | c.4421C>T p.A1474V | Missense Mutation (SNP) | VAF 65/224 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.226); catalogued as COSV54632269; called by muse, mutect2, varscan2
- ZNF619 | c.1077A>T p.K359N | Missense Mutation (SNP) | VAF 158/438 reads (36%) | SIFT tolerated (0.62); PolyPhen possibly damaging (0.864); catalogued as COSV59030865; called by muse, mutect2, varscan2
- ADAM28 | c.1298G>C p.C433S | Missense Mutation (SNP) | VAF 95/603 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CTXN3 | c.99T>G p.F33L | Missense Mutation (SNP) | VAF 111/466 reads (24%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.992); called by muse, mutect2
- FREM1 | c.1180T>C p.F394L | Missense Mutation (SNP) | VAF 167/524 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- MAGEC1 | c.2995C>T p.L999F | Missense Mutation (SNP) | VAF 131/168 reads (78%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- PIK3C3 | c.541del p.A181Lfs*8 | Frame Shift Del (DEL) | VAF 90/372 reads (24%) | called by mutect2, varscan2
- RASA1 | c.539+6_539+10del p.X180_splice | Splice Site (DEL) | VAF 153/338 reads (45%) | called by mutect2, varscan2
- SLC5A1 | c.1059A>C p.K353N | Missense Mutation (SNP) | VAF 78/410 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.075); called by muse, mutect2, varscan2
- TP53 | c.683_686del p.D228Vfs*18 | Frame Shift Del (DEL) | VAF 82/156 reads (53%) | called by mutect2, varscan2
- ZBTB38 | c.3482T>A p.V1161E | Missense Mutation (SNP) | VAF 225/561 reads (40%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ZNF326 | c.1439A>G p.D480G | Missense Mutation (SNP) | VAF 124/788 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.411); called by muse, mutect2, varscan2
- AMPD3 | c.147C>T p.I49= (on ENST00000396553 / NM_001025389.2; = p.I58= on NM_000480.3) | Silent (SNP) | VAF 121/432 reads (28%) | catalogued as rs141926261; called by muse, mutect2, varscan2
- C17orf97 | c.843C>T p.A281= | Silent (SNP) | VAF 6/140 reads (4%) | catalogued as COSV100789328; called by muse, mutect2
- CLNK | c.159C>T p.N53= | Silent (SNP) | VAF 60/449 reads (13%) | catalogued as rs1275424075; called by muse, mutect2, varscan2
- FAM47C | c.3081C>T p.D1027= | Silent (SNP) | VAF 115/157 reads (73%) | catalogued as COSV63725964, COSV63726299; called by muse, mutect2, varscan2
- GUCY2C | c.2370G>A p.R790= | Silent (SNP) | VAF 189/522 reads (36%) | catalogued as COSV53789323; called by muse, mutect2, varscan2
- KCNIP4 | c.234C>G p.A78= | Silent (SNP) | VAF 76/542 reads (14%) | called by muse, mutect2
- NBEAL1 | c.372A>T p.T124= | Silent (SNP) | VAF 203/847 reads (24%) | called by mutect2, varscan2
- NEMF | c.771C>T p.S257= | Silent (SNP) | VAF 85/426 reads (20%) | called by muse, mutect2, varscan2
- NPHS1 | c.2367C>T p.D789= | Silent (SNP) | VAF 12/223 reads (5%) | called by muse, mutect2
- SAXO1 | c.816T>C p.T272= | Silent (SNP) | VAF 62/137 reads (45%) | catalogued as rs373143412; called by muse, mutect2, varscan2
- VAV1 | c.1737A>G p.K579= | Silent (SNP) | VAF 47/265 reads (18%) | catalogued as COSV58392065; called by muse, mutect2, varscan2
- MYT1L | c.2027-49G>A | Intron (SNP) | VAF 48/81 reads (59%) | catalogued as rs781138432; called by muse, mutect2, varscan2
- PCID2 | c.37-95A>C | Intron (SNP) | VAF 3/23 reads (13%) | catalogued as COSV55814242; called by muse, mutect2
- PRPF31 | c.527+91T>C | Intron (SNP) | VAF 4/18 reads (22%) | catalogued as rs1182975463; called by muse, mutect2, varscan2
- SCNN1B | c.-2C>T | 5'UTR (SNP) | VAF 33/208 reads (16%) | catalogued as rs753938703; called by muse, mutect2, varscan2
- SH3BP5 | c.-6G>A | 5'UTR (SNP) | VAF 26/62 reads (42%) | called by muse, mutect2, varscan2
